Somatic mutation profile of tumor specimen TCGA-IN-AB1X-01A (aliquot TCGA-IN-AB1X-01A-11D-A397-08) from TCGA case TCGA-IN-AB1X, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 78.0 years (28,493 days).
Specimen TCGA-IN-AB1X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ec0a84c-4781-4fff-b4ff-0e9aae895d8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IN-AB1X-10E (Blood Derived Normal), aliquot TCGA-IN-AB1X-10E-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dcdd1141-184e-48fb-a6a7-5737d43c88f6

The open-access MAF lists 123 somatic variants for this specimen: 102 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 19, Frame Shift Del 3, Nonsense Mutation 3, Splice Region 1, In Frame Del 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TNNT3 | c.221G>A p.R74H (on ENST00000397301 / NM_001367846.1; = p.R63H on NM_006757.4) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434638, CM031754, COSV53486643; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACVRL1 | c.955G>A p.G319S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.888); catalogued as rs1085307414, CM1513225, COSV101188116; called by muse, mutect2, varscan2
- ADAD2 | c.1426G>A p.E476K (on ENST00000315906 / NM_001145400.2; = p.E558K on NM_139174.4) | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs754189973, COSV51893826; called by muse, mutect2, varscan2
- ADAM29 | c.2453C>T p.T818M | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.521); catalogued as rs201528348, COSV63666360; called by muse, mutect2, varscan2
- AKAP9 | c.32A>T p.E11V | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100663018; called by muse, mutect2, varscan2
- AKNA | c.2282T>A p.L761H | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99800973; called by muse, mutect2
- AP002512.3 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV54406614; called by muse, mutect2
- ARHGEF2 | c.113A>G p.N38S (on ENST00000361247 / NM_001162383.2; = p.N11S on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs758919022, COSV100561132; called by muse, mutect2, varscan2
- ASTN1 | c.3554C>T p.S1185F | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV62494603, COSV62503996; called by muse, mutect2, varscan2
- ATP1A2 | c.2219A>G p.K740R | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100768139; called by muse, mutect2, varscan2
- ATP6V1E1 | c.56T>C p.I19T | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1164200846, COSV99494444; called by muse, varscan2
- ATP7A | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.101); catalogued as COSV100431619; called by muse, mutect2, varscan2
- BRINP1 | c.1973T>A p.F658Y | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV99776774; called by muse, mutect2, varscan2
- C19orf47 | c.1115G>A p.S372N | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV63509266; called by muse, mutect2, varscan2
- CASKIN2 | c.1811A>C p.N604T | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.191); catalogued as COSV100050891; called by muse, mutect2, varscan2
- CFAP44 | c.1974T>A p.D658E | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs1238374470, COSV99870275; called by muse, mutect2, varscan2
- CNTN1 | c.2194A>G p.R732G | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV100751878; called by muse, mutect2, varscan2
- COL24A1 | c.2635G>A p.G879S | Missense Mutation (SNP) | VAF 43/265 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs905124553, COSV100993938; called by muse, mutect2
- COL4A2 | c.1735C>T p.R579C | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as rs755820436, COSV100847266; called by muse, mutect2, varscan2
- CSMD1 | c.9734G>T p.R3245I (on ENST00000520002; = p.R3244I on NM_033225.6) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100153160, COSV59387986; called by muse, mutect2
- DAG1 | c.2660G>A p.R887Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs776025512, COSV100445149; called by muse, mutect2, varscan2
- DENND4C | c.880T>G p.L294V | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100991546; called by muse, mutect2, varscan2
- DHX37 | c.2498G>A p.R833Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as rs757245596, COSV100439473; called by muse, mutect2, varscan2
- DLGAP5 | c.1939G>A p.V647I | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.057); catalogued as COSV99904130; called by muse, mutect2, varscan2
- DMD | c.1979A>G p.K660R | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as CD080810, COSV99925715; called by muse, mutect2, varscan2
- DMD | c.711A>T p.Q237H | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs778632674, COSV55856238; called by muse, mutect2, varscan2
- DNAH17 | c.7693C>A p.Q2565K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV101103312; called by muse, mutect2
- DOP1B | c.5675C>T p.S1892L | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as rs758445211, COSV101215795; called by muse, mutect2, varscan2
- DPP10 | c.2296A>G p.K766E | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.05); catalogued as COSV100071236; called by muse, mutect2, varscan2
- DPP9 | c.2452T>G p.F818V (on ENST00000598800; = p.F847V on NM_139159.5) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.017); catalogued as COSV99506472; called by muse, mutect2, varscan2
- DSCAM | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761826018, COSV101261377; called by muse, mutect2, varscan2
- E2F8 | c.1628C>T p.T543M | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV51463130; called by muse, mutect2, varscan2
- EBF3 | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.699); catalogued as rs913603139, COSV62471534; called by muse, mutect2, varscan2
- ENTPD3 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV100089046; called by muse, mutect2, varscan2
- EPHA7 | c.849C>G p.F283L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as COSV100994289; called by muse, mutect2, varscan2
- FCRL5 | c.2063C>A p.P688Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100709287, COSV62515935; called by muse, mutect2, varscan2
- FGB | c.1019T>G p.L340R | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100122550; called by muse, mutect2, varscan2
- GDPD1 | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1161799106, COSV99405329; called by muse, mutect2, varscan2
- GPRC5B | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.163); catalogued as rs746717252, COSV100245072; called by muse, mutect2, varscan2
- GRIA2 | c.2035T>C p.F679L | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99644550, COSV99645825; called by muse, mutect2, varscan2
- GRM7 | c.847G>A p.V283I | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs1284213715, COSV100738323; called by muse, mutect2, varscan2
- H2AZ2 | c.254G>T p.R85L | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as COSV99760618; called by muse, varscan2
- HMGB1 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.654); catalogued as COSV100361032; called by muse, mutect2, varscan2
- HTR3D | c.871G>T p.A291S (on ENST00000382489 / NM_001163646.2; = p.A118S on NM_182537.3) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.013); catalogued as COSV100488320; called by muse, mutect2, varscan2
- HTR5A | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as rs372841545, COSV99839487; called by muse, mutect2, varscan2
- IARS2 | c.1329T>A p.V443= | Splice Region (SNP) | VAF 9/86 reads (10%) | catalogued as COSV100228589; called by muse, mutect2, varscan2
- IFNGR1 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.903); catalogued as COSV100880525; called by muse, mutect2, varscan2
- IGHA1 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs765317688; called by muse, mutect2, varscan2
- ITPR1 | c.7631G>A p.R2544Q (on ENST00000354582; = p.R2489Q on NM_002222.7) | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773763162, COSV56978804; called by muse, mutect2, varscan2
- KCNB2 | c.141A>C p.E47D | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101579045, COSV73049565; called by muse, mutect2, varscan2
- KCND1 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as rs1557058590, COSV54413304; called by muse, mutect2
- KCNIP4 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as rs755731479, COSV100749718; called by muse, mutect2, varscan2
- KIRREL3 | c.108G>T p.K36N | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.95); catalogued as COSV101585872; called by muse, mutect2, varscan2
- KRT72 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs1402669376, COSV53377055; called by muse, mutect2, varscan2
- MATN4 | c.1475G>A p.R492H (on ENST00000372754; = p.R451H on NM_003833.4) | Missense Mutation (SNP) | VAF 19/92 reads (21%) | PolyPhen possibly damaging (0.49); catalogued as rs142628816; called by muse, mutect2, varscan2
- MCF2 | c.665A>C p.K222T | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV100645107; called by muse, mutect2
- MDN1 | c.8917C>A p.L2973I | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.081); catalogued as COSV101021798; called by muse, mutect2, varscan2
- MIER2 | c.32G>A p.S11N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.696); catalogued as rs993046374, COSV99316729; called by muse, mutect2, varscan2
- MKRN3 | c.941G>T p.C314F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100091129, COSV58812541; called by muse, mutect2, varscan2
- MUC16 | c.19351C>A p.P6451T | Missense Mutation (SNP) | VAF 54/252 reads (21%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.104); catalogued as rs762791427, COSV101201410; called by muse, mutect2, varscan2
- MYH2 | c.5153G>A p.R1718H | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755776701, COSV99820870; called by muse, mutect2, varscan2
- NAV3 | c.2815G>A p.D939N | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.075); catalogued as COSV99895017; called by muse, mutect2, varscan2
- NLGN1 | c.1969G>A p.D657N | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV100850097; called by muse, mutect2, varscan2
- NLGN4X | c.2128C>T p.R710C | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs763458960, COSV52016642, COSV52036801; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR10A2 | c.739T>G p.F247V | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.941); catalogued as COSV56299583; called by muse, mutect2, varscan2
- OR10A4 | c.392T>C p.L131S | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs900741519, COSV101139591; called by muse, mutect2, varscan2
- PAPOLB | c.205T>A p.L69I | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.903); catalogued as COSV101271612, COSV68203947; called by muse, mutect2, varscan2
- PAPPA2 | c.1466A>G p.E489G | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.343); catalogued as COSV100867097; called by muse, mutect2, varscan2
- PBRM1 | c.2171T>C p.M724T | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV56264447; called by muse, mutect2, varscan2
- PCDHGA1 | c.1469C>A p.S490Y | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.521); catalogued as rs1441551407, COSV100966065; called by muse, mutect2, varscan2
- PLEK2 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99371949; called by muse, mutect2, varscan2
- PLEKHH2 | c.1080G>A p.W360* | Nonsense Mutation (SNP) | VAF 12/62 reads (19%) | catalogued as COSV99175071; called by muse, mutect2, varscan2
- PLPPR4 | c.1847A>G p.E616G | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as COSV100926911, COSV64564307, COSV64565595; called by muse, mutect2, varscan2
- PRDM2 | c.1007A>T p.E336V | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.326); catalogued as COSV99342626; called by muse, mutect2, varscan2
- PRKAB1 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 41/226 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99982466; called by muse, mutect2, varscan2
- PTPRT | c.296A>G p.D99G | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62035631; called by muse, mutect2, varscan2
- RAET1L | c.255G>A p.M85I | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs202191913; called by muse, mutect2, varscan2
- RIC8B | c.929C>T p.T310M | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as rs371428855; called by muse, mutect2, varscan2
- SAMD9 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.401); catalogued as rs180705437, COSV101180361, COSV66074377; called by muse, mutect2, varscan2
- SCN10A | c.5243G>A p.W1748* | Nonsense Mutation (SNP) | VAF 15/72 reads (21%) | catalogued as COSV101479519; called by muse, mutect2, varscan2
- SCN7A | c.4256C>A p.T1419N | Missense Mutation (SNP) | VAF 34/185 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101313354; called by muse, mutect2, varscan2
- SEC14L5 | c.1288G>A p.V430M | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs189059128, COSV99229363; called by muse, mutect2, varscan2
- SFPQ | c.2078G>T p.R693I | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100599511; called by muse, mutect2, varscan2
- SLC28A2 | c.91G>A p.V31I | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1198186016, COSV100754802; called by muse, mutect2, varscan2
- STPG2 | c.647C>A p.P216H | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99761314; called by muse, mutect2, varscan2
- SUCO | c.1867A>C p.I623L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV55265351, COSV99743691; called by muse, mutect2, varscan2
- TCF4 | c.1920G>T p.K640N | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs773310534, COSV100610777; called by muse, mutect2, varscan2
- TGFBR1 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 19/110 reads (17%) | catalogued as CM112278, COSV66625032; called by muse, mutect2, varscan2
- TLR4 | c.497A>C p.K166T (on ENST00000355622 / NM_138554.5; = p.K126T on NM_003266.4) | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.276); catalogued as COSV100790692; called by muse, mutect2, varscan2
- TMEM237 | c.618G>A p.M206I (on ENST00000409883 / NM_001044385.3; = p.M198I on NM_152388.4) | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs767769973, COSV99636207; called by muse, mutect2, varscan2
- TULP2 | c.11A>C p.D4A | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV99618121; called by muse, mutect2
- UBE4B | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs749630439, COSV99477538; called by muse, mutect2, varscan2
- UMODL1 | c.1994G>A p.R665Q (on ENST00000408910 / NM_001004416.2; = p.R793Q on NM_173568.3) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs746597703, COSV61160708; called by muse, mutect2, varscan2
- VWA7 | c.1802T>C p.L601P | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV100991967; called by muse, mutect2
- ZNF248 | c.916T>G p.F306V | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV100627720; called by muse, mutect2, varscan2
- ZNF284 | c.458A>C p.K153T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.98); catalogued as COSV101399079; called by muse, mutect2, varscan2
- ZNF320 | c.303G>T p.W101C | Missense Mutation (SNP) | VAF 41/216 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV101206929; called by muse, mutect2, varscan2
- ZNF585A | c.1673C>A p.A558D (on ENST00000292841 / NM_001288800.2; = p.A503D on NM_152655.3) | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99493527; called by muse, mutect2, varscan2
- ARID1A | c.1242_1269del p.H415Pfs*9 | Frame Shift Del (DEL) | VAF 23/65 reads (35%) | called by mutect2, pindel
- EPHA2 | c.1667del p.F556Sfs*27 | Frame Shift Del (DEL) | VAF 6/43 reads (14%) | called by mutect2, pindel, varscan2
- FOXRED1 | c.250_252del p.K84del | In Frame Del (DEL) | VAF 16/84 reads (19%) | called by pindel, varscan2
- MSMB | c.227del p.P76Lfs*38 | Frame Shift Del (DEL) | VAF 37/262 reads (14%) | called by mutect2, pindel, varscan2
- ABCA13 | c.13920C>T p.F4640= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs769165172, COSV68947855; called by muse, mutect2, varscan2
- ADAMTS3 | c.2112C>G p.V704= | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as COSV99711936; called by muse, mutect2, varscan2
- BMI1 | c.498C>T p.C166= | Silent (SNP) | VAF 39/186 reads (21%) | catalogued as rs1224340935, COSV100936478; called by muse, mutect2, varscan2
- COL6A6 | c.288G>A p.K96= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs1162866281, COSV100650877; called by muse, mutect2, varscan2
- DENND4B | c.2007G>T p.V669= | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as COSV100768878; called by muse, mutect2, varscan2
- F8 | c.2169C>T p.A723= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as COSV100811873; called by muse, mutect2, varscan2
- FAT3 | c.4857C>A p.V1619= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as rs1174080787, COSV53083072, COSV99970553; called by muse, mutect2, varscan2
- FRY | c.1107C>G p.L369= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as COSV100969858, COSV66572388; called by muse, mutect2, varscan2
- HDAC9 | c.738G>A p.K246= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV101287324; called by muse, mutect2
- HMGCS2 | c.765G>A p.G255= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as rs745824260, COSV101024910; called by muse, mutect2, varscan2
- PAX9 | c.342G>A p.K114= | Silent (SNP) | VAF 19/141 reads (13%) | catalogued as COSV100825881; called by muse, mutect2, varscan2
- RAET1G | c.255G>A p.T85= | Silent (SNP) | VAF 18/342 reads (5%) | catalogued as rs1349402140, COSV100951694; called by muse, mutect2
- SBF1 | c.2661G>A p.P887= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs773683768, COSV100818006; called by muse, mutect2, varscan2
- SPANXN1 | c.84G>A p.E28= | Silent (SNP) | VAF 12/138 reads (9%) | catalogued as COSV100979437, COSV65122089; called by muse, mutect2
- TAP2 | c.108A>G p.P36= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV100885312; called by muse, mutect2, varscan2
- TRIM58 | c.627A>G p.R209= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs371162620, COSV100825269; called by muse, mutect2, varscan2
- ZNF584 | c.357C>T p.I119= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV100183405; called by muse, mutect2
- ZNF648 | c.1383G>A p.S461= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV60570038; called by muse, mutect2
- ZWILCH | c.1758C>T p.S586= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as rs1187816986, COSV100328933; called by muse, mutect2, varscan2
- ARHGAP28 | c.2030+1935A>C | Intron (SNP) | VAF 26/108 reads (24%) | catalogued as COSV99151396; called by muse, mutect2, varscan2
- CNOT1 | c.-2C>T | 5'UTR (SNP) | VAF 14/72 reads (19%) | catalogued as COSV100409975; called by mutect2, varscan2
